Somatic mutation profile of tumor specimen BA2157D (aliquot aq-BA2157D) from BEATAML1.0 case 2217, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.1 years (23,780 days).
Specimen BA2157D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc367cbb-db5b-4f50-858f-0b9caadc4548.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2560D (Solid Tissue Normal), aliquot aq-BA2560D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71519386-7ba0-4a8e-b62c-b52872bf7a2f

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 2, Splice Region 1, 3'UTR 1, Intron 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 50/240 reads (21%) | catalogued as rs397514641, CM000774, COSV62197492; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CDH18 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56927210, COSV99931214; called by muse, mutect2
- COL1A1 | c.2559+1G>T p.X853_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | catalogued as CS1110796; called by muse, mutect2
- DCHS1 | c.9841G>T p.A3281S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs1192783882; called by muse, mutect2
- DKKL1 | c.548C>A p.A183D | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV99678673; called by muse, varscan2
- PPFIBP1 | c.1329C>G p.I443M (on ENST00000318304 / NM_177444.3; = p.I426M on NM_003622.4) | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.129); catalogued as COSV57298648; called by muse, mutect2, varscan2
- SMCHD1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435114726; called by muse, mutect2, varscan2
- ECE1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 219/415 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- KXD1 | c.237C>A p.S79R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.958); called by muse, mutect2
- PPFIBP1 | c.1244C>T p.A415V (on ENST00000318304 / NM_177444.3; = p.A398V on NM_003622.4) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNW1 | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- UMODL1 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.339); called by muse, mutect2
- ZDHHC19 | c.144C>T p.F48= | Splice Region (SNP) | VAF 88/241 reads (37%) | called by muse, mutect2, varscan2
- ZNF287 | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- C1orf198 | c.615C>T p.A205= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as rs758911473, COSV64176465; called by muse, mutect2, varscan2
- FRRS1 | c.687A>G p.Q229= | Silent (SNP) | VAF 82/168 reads (49%) | catalogued as rs776343968; called by muse, mutect2, varscan2
- PPFIBP1 | c.1633+388C>G | Intron (SNP) | VAF 80/158 reads (51%) | called by muse, mutect2, varscan2
- SHF | c.-90A>G | 5'UTR (SNP) | VAF 89/198 reads (45%) | called by muse, mutect2, varscan2
- SRP19 | c.*95C>T | 3'UTR (SNP) | VAF 171/214 reads (80%) | catalogued as rs1467931228; called by muse, varscan2
